TCGA case TCGA-44-A479 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/851867cb-9ad0-4fdf-ac75-9bb0427ad440

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 74.0 years (27,024 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 75.2 years (27,461 days); Days to diagnosis: 437 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 437 days (1.2 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 256 days; Disease response: Tumor Free.
- Days to follow up: 392 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 486 days (1.3 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 60; FEV1/FVC before bronchodilator (%): 115; FEV1 before bronchodilator (% of reference): 102.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1962; Tobacco smoking quit year: 2002.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-A479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 280 mg.
  Slide TCGA-44-A479-01A-03-TSC: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-44-A479-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-A479-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: Yes; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2, New neoplasm event types: New tumor event type: New Primary Tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 486 days; disease-specific survival: no event (censored), 486 days; disease-free interval: no event (censored), 486 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 437 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-A479-01A-31D-A24C-01): tumor purity 0.36, ploidy 2.14, whole-genome doublings 0.
